MMRF case MMRF_2605 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/27a667a1-6a09-436d-b996-542333ac59cd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.3 years (22,744 days); ISS stage: I; Days to last known disease status: 660 days (1.8 years); Days to last follow up: 660 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 91 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 660.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 3.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.144 mg/dL; Immunoglobulin G 45.3 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 9 g/dL; Glucose 4.62 mmol/L.
- Day 95 (ECOG 1): M Protein 1.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.127 mg/dL; Immunoglobulin G 21.1 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.97 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 12.9 ×10⁹/L; Absolute Neutrophil 12.8 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.05 mmol/L; Glucose 4.35 mmol/L.
- Day 194 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.559 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.724 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 4.79 mmol/L.
- Day 274 (ECOG 1): Lactate Dehydrogenase 12.4 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 0.714 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 334 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.633 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 425 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 9.38 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 523 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.872 mg/dL; Immunoglobulin G 8.5 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 604 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.765 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.881 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 18 ×10⁹/L; Absolute Neutrophil 15.3 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -7: Weight: 50 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2605_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2605_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
